Somatic mutation profile of tumor specimen 0DUKI8 from CCDI case PBCLCB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Astroblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.3 years (3,413 days).
Specimen 0DUKI8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 18a79d50-4637-4c70-8ec5-2afee7241810.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUKIO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0cba1c9d-f91b-40fe-80e0-8d099f8b1ddd

The open-access MAF lists 12 somatic variants for this specimen: 5 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 5, Missense Mutation 5, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEP170B | c.2597G>A p.R866Q (on ENST00000453495; = p.R795Q on NM_015005.3) | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs372398127; called by muse, mutect2, varscan2
- DNMT3B | c.2155G>A p.V719M | Missense Mutation (SNP) | VAF 16/444 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52416305; called by muse, mutect2
- PCDHGB4 | c.389C>T p.T130M | Missense Mutation (SNP) | VAF 61/944 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV54011590; called by muse, mutect2
- PRKDC | c.5489A>G p.H1830R | Missense Mutation (SNP) | VAF 33/1060 reads (3%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.744); catalogued as rs1482856356; called by muse, mutect2
- GALNT13 | c.317A>T p.K106M | Missense Mutation (SNP) | VAF 370/924 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); called by muse, mutect2, varscan2
- KLHL23 | c.681C>T p.N227= | Silent (SNP) | VAF 30/908 reads (3%) | called by muse, mutect2
- RREB1 | c.4713C>T p.H1571= | Silent (SNP) | VAF 235/516 reads (46%) | catalogued as rs371285444; ClinVar: likely benign; called by muse, mutect2, varscan2
- RYR2 | c.12762C>T p.T4254= | Silent (SNP) | VAF 270/645 reads (42%) | catalogued as COSV63707833; called by muse, mutect2, varscan2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 48/1279 reads (4%) | called by muse, mutect2
- TOX4 | c.684A>C p.S228= | Silent (SNP) | VAF 276/668 reads (41%) | called by muse, mutect2, varscan2
- OCM | c.-77G>A | 5'UTR (SNP) | VAF 17/118 reads (14%) | catalogued as COSV99631522; called by muse, mutect2, varscan2
- TRPA1 | c.1195-74T>A | Intron (SNP) | VAF 10/233 reads (4%) | called by muse, mutect2
